Somatic mutation profile of tumor specimen TCGA-AB-2844-03B (aliquot TCGA-AB-2844-03B-01W-0728-08) from TCGA case TCGA-AB-2844, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.7 years (23,254 days).
Specimen TCGA-AB-2844-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69709a3d-55d7-4713-8ba0-8d60796bfdb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2844-11B (Solid Tissue Normal), aliquot TCGA-AB-2844-11B-01W-0729-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ac62603-f567-4ec2-b653-c3cf2cb5e93b

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC18A1 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as rs537191588, COSV52347306; called by muse, mutect2, varscan2
- SMC5 | c.1574A>T p.K525I | Missense Mutation (SNP) | VAF 63/117 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV63192137; called by muse, mutect2, varscan2
